Somatic mutation profile of tumor specimen 0DPAOG from CCDI case PBCDJM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 7.8 years (2,864 days).
Specimen 0DPAOG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d47da9d4-b8d8-4a86-bef1-b8588ba83368.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPAOC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a944345d-11ab-4a1d-9f89-b4ce6487927c

The open-access MAF lists 57 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Intron 7, 5'UTR 4, Frame Shift Del 3, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1F | c.5795C>T p.T1932M | Missense Mutation (SNP) | VAF 157/351 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs782460359, COSV59903235; called by muse, mutect2, varscan2
- CARMIL3 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 124/297 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1253774287; called by muse, mutect2, varscan2
- CROCC2 | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 169/635 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs543602371; called by muse, mutect2, varscan2
- DNAH17 | c.8755G>A p.E2919K | Missense Mutation (SNP) | VAF 70/650 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as rs750434977, COSV101101263; called by muse, mutect2, varscan2
- EPX | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 650/1029 reads (63%) | SIFT tolerated (0.52); PolyPhen benign (0.12); catalogued as rs746252508; called by muse, mutect2, varscan2
- MUC12 | c.8076del p.T2693Pfs*93 (on ENST00000379442; = p.T2550Pfs*93 on NM_001164462.1) | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | catalogued as rs1554342786; called by mutect2, varscan2
- PLEC | c.2785del p.V929Cfs*3 (on ENST00000322810 / NM_201380.4; = p.V819Cfs*3 on NM_000445.5) | Frame Shift Del (DEL) | VAF 122/878 reads (14%) | catalogued as COSV59600317; called by mutect2, varscan2
- SETD7 | c.1030A>G p.K344E | Missense Mutation (SNP) | VAF 71/512 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs763632116, COSV56801446; called by muse, mutect2, varscan2
- SORCS1 | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 242/463 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146666715, COSV53853541; called by muse, mutect2, varscan2
- SYCN | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs558645393; called by muse, mutect2, varscan2
- TCF7L2 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 98/220 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.533); catalogued as COSV60508872; called by muse, mutect2, varscan2
- TFAP4 | c.454del p.R152Gfs*4 | Frame Shift Del (DEL) | VAF 86/218 reads (39%) | catalogued as COSV52597741; called by mutect2, varscan2
- ZNF143 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 278/1004 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs768165831, COSV55179882; called by muse, mutect2, varscan2
- ZNF282 | c.1919G>T p.R640L | Missense Mutation (SNP) | VAF 56/544 reads (10%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.852); catalogued as COSV100021668; called by muse, mutect2
- ADRB2 | c.667T>C p.F223L | Missense Mutation (SNP) | VAF 212/655 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- APOBEC3G | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 278/641 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CDH20 | c.707A>T p.E236V | Missense Mutation (SNP) | VAF 259/629 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- COL20A1 | c.2432T>G p.V811G | Missense Mutation (SNP) | VAF 125/591 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DRC7 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- FEZF1 | c.203A>T p.N68I | Missense Mutation (SNP) | VAF 89/423 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- GUCY2D | c.3029A>G p.E1010G | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 53/1724 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- MAF1 | c.16A>G p.N6D | Missense Mutation (SNP) | VAF 178/1299 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- MYCBP2 | c.13477C>T p.P4493S (on ENST00000357337; = p.P4531S on NM_015057.5) | Missense Mutation (SNP) | VAF 251/672 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- MYO3A | c.4322T>C p.I1441T | Missense Mutation (SNP) | VAF 251/969 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRSS16 | c.1283A>C p.Y428S | Missense Mutation (SNP) | VAF 225/560 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SENP5 | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 464/950 reads (49%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3RF1 | c.290T>C p.L97S | Missense Mutation (SNP) | VAF 46/401 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC13A1 | c.1342G>T p.G448C | Missense Mutation (SNP) | VAF 302/1212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYF2 | c.426C>G p.I142M | Missense Mutation (SNP) | VAF 323/779 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SYPL1 | c.459C>A p.D153E | Missense Mutation (SNP) | VAF 154/764 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TENM2 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 486/825 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- UBA1 | c.3041C>G p.P1014R | Missense Mutation (SNP) | VAF 137/348 reads (39%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- UBR3 | c.1564T>G p.S522A | Missense Mutation (SNP) | VAF 98/1693 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- ZNF534 | c.1228C>T p.L410F (on ENST00000332323 / NM_001143939.3; = p.L397F on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/311 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, varscan2
- BCAS1 | c.321C>G p.T107= | Silent (SNP) | VAF 202/952 reads (21%) | called by muse, mutect2, varscan2
- GRIK2 | c.2103G>A p.T701= | Silent (SNP) | VAF 325/785 reads (41%) | catalogued as rs556175755, COSV59714508, COSV59715838; called by muse, mutect2, varscan2
- HTR1B | c.24C>T p.C8= | Silent (SNP) | VAF 67/426 reads (16%) | called by muse, mutect2, varscan2
- LORICRIN | c.252C>G p.S84= | Silent (SNP) | VAF 64/189 reads (34%) | called by muse, mutect2
- MED12L | c.1170C>T p.S390= | Silent (SNP) | VAF 263/895 reads (29%) | catalogued as rs1002344651, COSV56383458; called by muse, mutect2, varscan2
- OR7C1 | c.870C>T p.Y290= | Silent (SNP) | VAF 116/565 reads (21%) | called by muse, mutect2, varscan2
- OTOGL | c.6516G>A p.Q2172= (on ENST00000547103; = p.Q2163= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 222/968 reads (23%) | catalogued as COSV54018784; called by muse, mutect2, varscan2
- PVRIG | c.204C>G p.G68= | Silent (SNP) | VAF 221/448 reads (49%) | called by muse, mutect2, varscan2
- TLR9 | c.2740C>T p.L914= | Silent (SNP) | VAF 17/127 reads (13%) | called by muse, mutect2, varscan2
- AC046195.1 | n.680+5886G>T | Intron (SNP) | VAF 373/2741 reads (14%) | called by muse, mutect2, varscan2
- AMBN | c.-82dup | 5'UTR (INS) | VAF 40/95 reads (42%) | called by mutect2, varscan2
- CCDC50 | c.-93C>G | 5'UTR (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- COL6A2 | c.2461+2454A>T | Intron (SNP) | VAF 53/102 reads (52%) | called by muse, mutect2, varscan2
- GULP1 | c.843+1717G>A | Intron (SNP) | VAF 56/425 reads (13%) | catalogued as rs1326302130; called by muse, mutect2, varscan2
- JARID2 | c.-70dup | 5'UTR (INS) | VAF 42/94 reads (45%) | catalogued as rs917085002; called by mutect2, varscan2
- KRT6A | c.912+14C>A | Intron (SNP) | VAF 180/732 reads (25%) | called by mutect2, varscan2
- MVK | c.*11C>T | 3'UTR (SNP) | VAF 103/496 reads (21%) | catalogued as rs104895345; ClinVar: not provided; called by muse, mutect2, varscan2
- PNP | c.285+43G>C | Intron (SNP) | VAF 72/128 reads (56%) | called by muse, mutect2, varscan2
- PTCD1 | c.*516C>T | 3'UTR (SNP) | VAF 142/628 reads (23%) | catalogued as rs563436821; called by muse, mutect2, varscan2
- SSBP1 | c.-6G>C | 5'UTR (SNP) | VAF 118/1257 reads (9%) | called by muse, mutect2
- TJP2 | c.1521-86G>C | Intron (SNP) | VAF 57/108 reads (53%) | called by muse, mutect2, varscan2
- UBE2Q1 | c.875+79G>A | Intron (SNP) | VAF 56/184 reads (30%) | called by muse, mutect2, varscan2
